CPTAC case C3N-01362 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/15c01b4c-2fc0-42e7-a008-13ab8c4d367b

Demographics
Sex at birth: male; Race: white; Year of birth: 1957; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Oncocytoma: ICD-O-3 morphology code: 8290/0; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 59.6 years (21,766 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G1; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,815 days (5.0 years); Progression or recurrence: no; Days to last follow up: 1,815 days (5.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 6 cm; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (6 entries)
- Days to follow up: 371 days (1.0 years); Disease response: Tumor Free.
- Days to follow up: 736 days (2.0 years); Disease response: Tumor Free.
- Days to follow up: 1,100 days (3.0 years); Disease response: Tumor Free.
- Days to follow up: 1,513 days (4.1 years); Disease response: Complete Response.
- Days to follow up: 1,513 days (4.1 years); Disease response: Tumor Free.
- Days to follow up: 1,815 days (5.0 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 88 kg; Height: 170 cm; BMI: 30.45.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 25; Cigarettes per day: 20; Tobacco smoking onset year: 1977; Tobacco smoking quit year: 2002; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 25.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01362-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -1 day; Initial weight: 278 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01362-21: Section location: Middle; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3N-01362-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
